Somatic mutation profile of tumor specimen TCGA-EE-A20I-06A (aliquot TCGA-EE-A20I-06A-11D-A196-08) from TCGA case TCGA-EE-A20I, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.1 years (29,259 days).
Specimen TCGA-EE-A20I-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e97b65a-cf40-47ab-a3c3-773402e84ece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A20I-10A (Blood Derived Normal), aliquot TCGA-EE-A20I-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2871f8c-cad5-4fd2-bce2-21cc2709e208

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66106814; called by muse, mutect2, varscan2
- ACBD3 | c.663G>C p.R221S | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as rs191893895, COSV64730766, COSV64730805; called by muse, mutect2, varscan2
- BRINP3 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs761166562, COSV66519346, COSV66532947; called by muse, mutect2, varscan2
- CAB39L | c.691-2A>G p.X231_splice | Splice Site (SNP) | VAF 23/66 reads (35%) | catalogued as COSV61715929; called by muse, mutect2, varscan2
- GMPPB | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57539441; called by muse, mutect2, varscan2
- GRK7 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1055657448, COSV53824242; called by muse, mutect2, varscan2
- MROH2B | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV68187092; called by muse, mutect2
- PDGFC | c.860G>C p.C287S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.998); catalogued as COSV56849010, COSV56851931; called by muse, mutect2, varscan2
- PEAK1 | c.4132C>T p.R1378W | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414780018; called by muse, mutect2
- RYR2 | c.5072A>G p.N1691S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV63700196; called by muse, mutect2, varscan2
- TAS2R9 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359845383, COSV53689981; called by muse, mutect2, varscan2
- UGT3A1 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1245218302, COSV57100683; called by muse, mutect2, varscan2
- CNTN3 | c.101_120del p.N34Ifs*4 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- AMACR | c.756T>A p.S252= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV56873750; called by muse, mutect2, varscan2
- FMN2 | c.549C>A p.I183= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV60442308; called by muse, mutect2, varscan2
- HEPACAM | c.783C>T p.A261= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV53431234; called by muse, mutect2, varscan2
- MROH2B | c.712C>T p.L238= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs984103935, COSV68187095; called by muse, varscan2
- RAPGEF2 | c.3723T>A p.A1241= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as COSV52431344; called by muse, mutect2, varscan2
- Vault | n.50T>A | RNA (SNP) | VAF 7/28 reads (25%) | catalogued as rs765051656; called by muse, mutect2, varscan2
